Somatic mutation profile of tumor specimen TCGA-78-7539-01A (aliquot TCGA-78-7539-01A-11D-2063-08) from TCGA case TCGA-78-7539, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.1 years (27,445 days).
Specimen TCGA-78-7539-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e1126a7-3efb-45a7-b7c3-ccaea5687c70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7539-10A (Blood Derived Normal), aliquot TCGA-78-7539-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/710cf1c6-2f90-4e98-a60d-721f72624425

The open-access MAF lists 527 somatic variants for this specimen: 394 protein-altering or splice-affecting, 124 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 342, Silent 124, Nonsense Mutation 32, Frame Shift Del 8, Splice Site 8, RNA 4, Intron 3, Splice Region 2, Frame Shift Ins 1, 3'UTR 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA6 | c.737G>C p.R246T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52637397, COSV52637557, COSV52641215; called by muse, mutect2
- ABCC10 | c.2535G>T p.E845D (on ENST00000372530 / NM_001198934.2; = p.E817D on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV55086550; called by muse, mutect2, varscan2
- ABCC3 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV53319867; called by muse, mutect2, varscan2
- ACSBG1 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as rs1170809449, COSV51905004; called by muse, mutect2, varscan2
- ACTG1 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); catalogued as rs782638106, COSV59510117; called by muse, mutect2, varscan2
- ADAMTS20 | c.2910G>T p.W970C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101166130; called by muse, mutect2, varscan2
- ADAMTS20 | c.2909G>A p.W970* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV101166131; called by muse, mutect2, varscan2
- ADD1 | c.1717G>C p.E573Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.881); catalogued as COSV53268140; called by muse, mutect2, varscan2
- ADGRA3 | c.3604G>T p.V1202L | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs141222776, COSV51562160; called by muse, mutect2, varscan2
- ADGRE2 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV59692876; called by muse, mutect2, varscan2
- ADGRF5 | c.491G>T p.C164F | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV51932478; called by muse, mutect2, varscan2
- ADGRG4 | c.4021C>T p.P1341S | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.132); catalogued as COSV54953758; called by muse, mutect2, varscan2
- AFF2 | c.1905G>C p.E635D | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV53985068; called by muse, mutect2, varscan2
- AGFG2 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); catalogued as COSV53544790; called by muse, mutect2, varscan2
- AGRN | c.1429G>C p.A477P | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65068966; called by muse, mutect2, varscan2
- AGXT2 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV51485465; called by muse, mutect2, varscan2
- AHCYL2 | c.1252G>C p.V418L | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV61486451; called by muse, mutect2, varscan2
- AHNAK | c.2609G>T p.G870V | Missense Mutation (SNP) | VAF 70/257 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV57210453; called by muse, mutect2, varscan2
- AHSP | c.54C>G p.F18L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV56528783; called by muse, mutect2, varscan2
- AIPL1 | c.815G>C p.R272P | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as CM167090, COSV100006183, COSV51506645, COSV51506697; called by muse, mutect2, varscan2
- AKAP1 | c.2433-2A>C p.X811_splice | Splice Site (SNP) | VAF 21/160 reads (13%) | catalogued as COSV61805402; called by muse, mutect2, varscan2
- AKAP13 | c.1556C>G p.S519C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs201778847, COSV63453823; called by muse, mutect2, varscan2
- AL441992.2 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56913223; called by muse, mutect2, varscan2
- ALDH7A1 | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.765); catalogued as rs765153843, COSV68628934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH1 | c.417G>C p.E139D | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as rs371958188; called by muse, mutect2, varscan2
- AMFR | c.1271T>G p.F424C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51920721; called by muse, mutect2, varscan2
- AMPD2 | c.239C>A p.S80* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV56647192; called by muse, mutect2, varscan2
- AMY2A | c.176C>A p.P59Q | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70214415; called by muse, mutect2, varscan2
- ANK2 | c.8321G>T p.G2774V | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.155); catalogued as COSV52156088; called by muse, mutect2, varscan2
- ANKAR | c.4063G>A p.E1355K | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs1248832561, COSV51462186; called by muse, mutect2
- ANKRD30A | c.2912G>T p.C971F (on ENST00000611781; = p.C915F on NM_052997.2) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV64608308; called by muse, mutect2, varscan2
- APOB | c.12379G>A p.D4127N | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs769785870, COSV51924599; called by muse, mutect2
- ARHGAP5 | c.4505T>C p.I1502T (on ENST00000345122 / NM_001030055.2; = p.I1501T on NM_001173.3) | Missense Mutation (SNP) | VAF 72/126 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); catalogued as rs1225046744, COSV53735102; called by muse, mutect2, varscan2
- ARHGDIB | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1282620816, COSV56762948; called by muse, mutect2, varscan2
- ARHGEF10 | c.3155-1G>C p.X1052_splice (on ENST00000398564; = p.X1027_splice on NM_014629.4) | Splice Site (SNP) | VAF 24/104 reads (23%) | catalogued as COSV50646032; called by muse, mutect2, varscan2
- ARHGEF11 | c.3734C>T p.S1245F | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.346); catalogued as rs1230975581, COSV59353655; called by muse, mutect2
- ASB5 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs761591211, COSV56669853; called by muse, mutect2, varscan2
- ATRNL1 | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.603); catalogued as COSV61802241; called by muse, mutect2, varscan2
- ATXN2 | c.2642C>A p.T881N (on ENST00000550104; = p.T721N on NM_002973.4) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101112640; called by muse, mutect2, varscan2
- B4GALNT2 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV55925618; called by muse, mutect2, varscan2
- BARHL1 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.532); catalogued as COSV55037399; called by muse, mutect2, varscan2
- BBOX1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54190455; called by muse, mutect2, varscan2
- BBOX1 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99589529; called by muse, mutect2, varscan2
- BMP5 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as COSV63702498; called by muse, mutect2, varscan2
- BRAF | c.1301C>G p.S434* (on ENST00000288602 / NM_001374244.1; = p.S394* on NM_004333.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV56140830; called by muse, mutect2, varscan2
- BRCA2 | c.9349C>A p.H3117N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV66452055; called by muse, mutect2, varscan2
- BTBD9 | c.1128A>T p.K376N | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV58423670; called by muse, mutect2, varscan2
- BTRC | c.901G>C p.E301Q (on ENST00000370187 / NM_033637.4; = p.E265Q on NM_003939.5) | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV64579276; called by muse, mutect2, varscan2
- C11orf16 | c.1244A>G p.H415R | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV55148776; called by muse, varscan2
- C1orf116 | c.283+1del p.X95_splice | Splice Site (DEL) | VAF 30/133 reads (23%) | catalogued as COSV63944286; called by mutect2, pindel, varscan2
- C2CD6 | c.1592A>T p.D531V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53793603; called by muse, mutect2
- C2orf73 | c.627G>C p.E209D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV58310643; called by muse, mutect2
- C6orf89 | c.55G>T p.D19Y (on ENST00000373685; = p.D26Y on NM_152734.4) | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62101621; called by muse, mutect2, varscan2
- CABYR | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV59110692; called by muse, mutect2, varscan2
- CASP2 | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60081803; called by muse, mutect2, varscan2
- CAST | c.1549G>A p.E517K (on ENST00000341926; = p.E600K on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV57086884; called by muse, mutect2, varscan2
- CCDC141 | c.3232C>G p.Q1078E | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV55372019; called by muse, mutect2, varscan2
- CCDC141 | c.3064C>G p.H1022D | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV55372040; called by muse, mutect2, varscan2
- CCDC158 | c.1109A>T p.Q370L | Missense Mutation (SNP) | VAF 59/76 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66355606; called by muse, mutect2, varscan2
- CCDC170 | c.1219C>G p.Q407E | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV53339667; called by muse, mutect2, varscan2
- CCDC181 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63156206; called by muse, mutect2, varscan2
- CCIN | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58724415; called by muse, mutect2, varscan2
- CCNF | c.96C>G p.I32M | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV53539352; called by muse, varscan2
- CD1D | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.106); catalogued as rs765499678, COSV63808821; called by muse, mutect2
- CD300E | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV60790300; called by muse, mutect2, varscan2
- CDH10 | c.1232C>A p.P411Q | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52577523; called by muse, mutect2, varscan2
- CDH8 | c.1523G>T p.G508V | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV54855004, COSV54860584; called by muse, mutect2, varscan2
- CDS2 | c.1206-2A>G p.X402_splice | Splice Site (SNP) | VAF 24/53 reads (45%) | catalogued as COSV66896103; called by muse, mutect2, varscan2
- CELSR1 | c.6029C>G p.S2010C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1001393474, COSV53087765; called by muse, mutect2
- CELSR1 | c.4792C>G p.L1598V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53087781; called by muse, mutect2, varscan2
- CELSR2 | c.7228G>A p.G2410S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs200447722, COSV54769637; called by muse, mutect2, varscan2
- CEP350 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV62485922; called by muse, mutect2, varscan2
- CFAP126 | c.433C>G p.P145A | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV61367894, COSV61369016; called by muse, mutect2, varscan2
- CFAP251 | c.1852C>T p.Q618* | Nonsense Mutation (SNP) | VAF 32/163 reads (20%) | catalogued as COSV56608924; called by muse, mutect2, varscan2
- CFAP43 | c.1734C>G p.I578M | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1204590706, COSV53377405; called by muse, mutect2, varscan2
- CFHR4 | c.1121C>G p.S374C (on ENST00000367416 / NM_001201551.2; = p.S128C on NM_006684.5) | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.827); catalogued as COSV52227274, COSV52229345; called by muse, mutect2, varscan2
- CHCHD1 | c.144G>C p.E48D | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV65708228; called by muse, varscan2
- CHD3 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.027); catalogued as COSV57874115; called by muse, mutect2, varscan2
- CHRNB4 | c.1070C>A p.A357D | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV55715631; called by muse, mutect2, varscan2
- CLEC17A | c.515A>G p.Y172C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs750812921, COSV60427398; called by muse, varscan2
- CLPTM1 | c.1175C>G p.S392C | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61611648; called by muse, mutect2, varscan2
- CLTCL1 | c.526del p.R176Vfs*19 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as COSV99595694; called by mutect2, pindel
- COL12A1 | c.8578G>T p.G2860* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as COSV59393537; called by muse, mutect2, varscan2
- COL6A2 | c.1895C>T p.T632I | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1042338524, COSV100153905, COSV56002999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.7406G>T p.G2469V | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60394043; called by muse, mutect2, varscan2
- COL9A1 | c.2581G>T p.G861C | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57882206; called by muse, mutect2, varscan2
- COL9A1 | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57882234; called by muse, mutect2, varscan2
- CPE | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT tolerated (0.89); PolyPhen benign (0.223); catalogued as COSV68579887; called by muse, mutect2, varscan2
- CSPG4 | c.6151G>T p.A2051S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV57893537; called by muse, varscan2
- CTNNA3 | c.1255C>T p.H419Y | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV65615888; called by muse, mutect2
- CTXN3 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65218399; called by muse, mutect2, varscan2
- CUL5 | c.1706G>T p.R569I | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67608639; called by muse, mutect2
- CYP7B1 | c.260-1G>A p.X87_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV59586306; called by muse, mutect2, varscan2
- DAW1 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.757); catalogued as rs199504696, COSV59364769; called by muse, mutect2, varscan2
- DGKZ | c.2641G>C p.E881Q (on ENST00000454345 / NM_001105540.2; = p.E693Q on NM_003646.4) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV58987224; called by muse, mutect2, varscan2
- DHX38 | c.2044G>A p.V682I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); catalogued as rs746331841, COSV99194227; called by mutect2, varscan2
- DHX9 | c.2711A>T p.H904L | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV62359003; called by muse, mutect2
- DIO2 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 16/27 reads (59%) | catalogued as COSV70445047; called by muse, mutect2, varscan2
- DNAH9 | c.9903G>T p.E3301D | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.06); catalogued as rs1461369615, COSV52344873; called by muse, mutect2, varscan2
- DSCAM | c.896A>T p.Y299F | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV68024953; called by muse, mutect2, varscan2
- EFS | c.1021C>A p.P341T | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV53731902; called by muse, mutect2, varscan2
- ENGASE | c.2219C>G p.S740* | Nonsense Mutation (SNP) | VAF 7/73 reads (10%) | catalogued as COSV56135114; called by muse, mutect2, varscan2
- ERICH3 | c.421G>T p.G141* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as COSV58604293; called by muse, mutect2, varscan2
- ESRRB | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55060558; called by muse, mutect2, varscan2
- EXOG | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs766378816, COSV55063111; called by muse, mutect2, varscan2
- FAM166B | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as COSV63428351; called by muse, mutect2, varscan2
- FAM47A | c.2263C>T p.Q755* | Nonsense Mutation (SNP) | VAF 28/141 reads (20%) | catalogued as COSV60495784; called by muse, mutect2, varscan2
- FAM47C | c.1741C>A p.H581N | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.087); catalogued as COSV63725679; called by muse, mutect2, varscan2
- FANCB | c.592C>G p.Q198E | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.121); catalogued as rs1456376131, COSV60759446; called by muse, mutect2, varscan2
- FBH1 | c.399G>T p.Q133H (on ENST00000362091 / NM_178150.3; = p.Q184H on NM_032807.4) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV62982242; called by muse, mutect2, varscan2
- FBXO5 | c.710G>C p.R237T | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV57670356, COSV57670695; called by muse, mutect2
- FCER1A | c.300G>C p.E100D | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV63666942; called by muse, mutect2
- FGFRL1 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.351); catalogued as rs200852436, COSV99294897; called by muse, mutect2, varscan2
- FGR | c.846G>A p.W282* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV64969435; called by muse, mutect2, varscan2
- FHOD1 | c.87C>G p.F29L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV50759895; called by muse, mutect2, varscan2
- FHOD3 | c.1520G>C p.R507T (on ENST00000359247 / NM_001281739.3; = p.R524T on NM_025135.5) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV57170601; called by muse, mutect2, varscan2
- FIBP | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57027821; called by muse, mutect2, varscan2
- FLI1 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs1355289095, COSV61379989; called by muse, mutect2
- FNBP4 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs1429969447, COSV55447769; called by muse, mutect2, varscan2
- FREM1 | c.6294C>A p.H2098Q | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV66521797; called by muse, mutect2, varscan2
- FRMD1 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV51961293, COSV51965491; called by muse, mutect2, varscan2
- FRMPD4 | c.2383G>T p.E795* | Nonsense Mutation (SNP) | VAF 38/172 reads (22%) | catalogued as COSV101044014, COSV66213612; called by muse, mutect2, varscan2
- FSHR | c.1843C>T p.H615Y | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58621594; called by muse, mutect2, varscan2
- FXN | c.400G>C p.D134H (on ENST00000377270; = p.D209H on NM_000144.5) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV66009683; called by muse, mutect2, varscan2
- GANAB | c.1823C>T p.S608F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60461425, COSV60462204; called by muse, mutect2, varscan2
- GATA5 | c.584T>G p.L195R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV53345649; called by mutect2, varscan2
- GCAT | c.718G>T p.G240W | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50648852; called by muse, mutect2
- GHR | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV50110011; called by muse, mutect2, varscan2
- GLMP | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as COSV55294567; called by muse, mutect2
- GOLGA4 | c.4150C>T p.Q1384* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV62710265; called by muse, mutect2, varscan2
- GP1BA | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56699021; called by muse, mutect2, varscan2
- GPC6 | c.1633T>A p.C545S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100988229; called by muse, mutect2, varscan2
- GPX5 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 62/126 reads (49%) | catalogued as COSV69079292; called by muse, mutect2, varscan2
- GRIN2B | c.2553G>T p.M851I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.526); catalogued as COSV74205533; called by muse, mutect2, varscan2
- H1-0 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.132); catalogued as COSV50648849; called by muse, mutect2, varscan2
- H2BC7 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.915); catalogued as rs745529878, COSV61911800; called by muse, mutect2, varscan2
- HBD | c.394C>G p.Q132E | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV53082387; called by muse, mutect2, varscan2
- HECA | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs1387562663, COSV62769014; called by muse, mutect2, varscan2
- HECTD1 | c.4931C>G p.S1644* | Nonsense Mutation (SNP) | VAF 40/207 reads (19%) | catalogued as COSV67945867; called by muse, mutect2, varscan2
- HIVEP1 | c.3878C>G p.S1293* | Nonsense Mutation (SNP) | VAF 10/105 reads (10%) | catalogued as COSV65100482; called by muse, mutect2, varscan2
- HS3ST1 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 46/166 reads (28%) | catalogued as COSV50023338; called by muse, mutect2, varscan2
- ICAM5 | c.2269G>A p.G757R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (1); catalogued as rs759588861, COSV55746874; called by muse, varscan2
- ICE1 | c.6316G>A p.G2106S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56822571, COSV56827026; called by muse, mutect2, varscan2
- IFI44 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs749501287, COSV66074496; called by muse, mutect2, varscan2
- IL7 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV55672903, COSV55674084, COSV99805072; called by muse, mutect2, varscan2
- ILF2 | c.14G>C p.R5T | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.587); catalogued as COSV62627172, COSV62627971; called by muse, mutect2
- INPP5D | c.2659C>T p.H887Y (on ENST00000445964 / NM_001017915.3; = p.H886Y on NM_005541.5) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as COSV64036535; called by muse, mutect2, varscan2
- INPP5F | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.824); catalogued as COSV62820764; called by muse, mutect2, varscan2
- INTS2 | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.187); catalogued as rs767384274, COSV52152626; called by muse, mutect2, varscan2
- INTS6 | c.679G>T p.V227L | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV60877535; called by muse, mutect2, varscan2
- IQSEC2 | c.1088T>A p.M363K (on ENST00000642864 / NM_001111125.3; = p.M158K on NM_015075.2) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64724775; called by muse, mutect2, varscan2
- IRF8 | c.73G>T p.G25* | Nonsense Mutation (SNP) | VAF 32/101 reads (32%) | catalogued as COSV99236218; called by muse, mutect2, varscan2
- IRF8 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99236227; called by muse, mutect2, varscan2
- ITGA2 | c.1952G>C p.S651T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs774931520, COSV56858626; called by muse, mutect2, varscan2
- ITGAE | c.978C>G p.I326M | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.401); catalogued as COSV53992733; called by muse, mutect2, varscan2
- JAKMIP2 | c.2199C>G p.I733M | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.466); catalogued as COSV54601862; called by muse, mutect2, varscan2
- JARID2 | c.3527G>A p.R1176Q | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs367941514; called by muse, mutect2, varscan2
- JUN | c.849del p.V284* | Frame Shift Del (DEL) | VAF 38/105 reads (36%) | catalogued as COSV64664160; called by mutect2, pindel, varscan2
- KATNIP | c.3742A>G p.I1248V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV55178401; called by muse, mutect2, varscan2
- KCNH2 | c.2143G>C p.A715P | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV51134976; called by muse, mutect2, varscan2
- KCNK7 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV58419213; called by muse, mutect2, varscan2
- KCNT2 | c.1029G>T p.Q343H | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV54074234; called by muse, mutect2, varscan2
- KDM4C | c.1497A>T p.K499N | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV67185677; called by muse, mutect2, varscan2
- KIF2A | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV66945279; called by muse, varscan2
- KIFC1 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.186); catalogued as rs981774834, COSV70822825; called by muse, mutect2, varscan2
- KIN | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.482); catalogued as rs762761840, COSV65430338; called by mutect2, varscan2
- KLF5 | c.483C>G p.I161M | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs747783347, COSV66614099, COSV66614399; called by muse, mutect2
- KLHL34 | c.1576G>T p.G526C | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65279117; called by muse, mutect2
- KRT75 | c.1031C>G p.T344S | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.206); catalogued as COSV52870869, COSV52872073; called by muse, mutect2, varscan2
- LAMA1 | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565276715, COSV101056658, COSV67535195; called by muse, mutect2, varscan2
- LAX1 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 29/455 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV65849175; called by muse, mutect2
- LIFR | c.820C>G p.Q274E | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV54688273; called by muse, mutect2, varscan2
- LRP12 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs557441495, COSV52627705; called by muse, mutect2, varscan2
- LRRC2 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV56125410, COSV56125686; called by muse, mutect2, varscan2
- LRRC4C | c.899A>T p.H300L | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV53422925; called by muse, mutect2, varscan2
- LRRTM3 | c.1565T>A p.F522Y | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); catalogued as COSV63664136; called by muse, mutect2
- MAGEA1 | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV63118423; called by muse, mutect2, varscan2
- MAGEA4 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1329712281, COSV52340065; called by muse, mutect2, varscan2
- MAGEB6 | c.602C>A p.T201K | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV66871774, COSV66872105; called by muse, mutect2, varscan2
- MAGOHB | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57898305; called by muse, mutect2, varscan2
- MAP3K5 | c.1544T>C p.V515A | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1472746060, COSV62888650; called by muse, mutect2, varscan2
- MAP3K7 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV65232650; called by muse, mutect2, varscan2
- MCFD2 | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1162286700, COSV60177920; called by muse, mutect2, varscan2
- MDGA1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 67/245 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs376372020; called by muse, mutect2, varscan2
- ME3 | c.303G>C p.Q101H | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV60164670; called by muse, mutect2, varscan2
- MED1 | c.4579A>G p.S1527G | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV56123961; called by muse, mutect2, varscan2
- MICAL2 | c.1744G>C p.D582H | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56318817, COSV56319255; called by muse, mutect2, varscan2
- MLH1 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV51616782; called by muse, mutect2, varscan2
- MLXIP | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59834701; called by muse, mutect2
- MMP16 | c.402C>A p.Y134* | Nonsense Mutation (SNP) | VAF 76/228 reads (33%) | catalogued as COSV54159956, COSV99690627; called by muse, mutect2, varscan2
- MORF4L2 | c.703A>T p.I235F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.7); catalogued as COSV64610894; called by muse, mutect2, varscan2
- MOV10L1 | c.2926G>A p.E976K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as rs756106532, COSV53169832; called by muse, mutect2, varscan2
- MRPS30 | c.600C>T p.L200= | Splice Region (SNP) | VAF 12/80 reads (15%) | catalogued as COSV72361252; called by muse, mutect2, varscan2
- MS4A6A | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60618019; called by muse, mutect2, varscan2
- MTR | c.3248C>G p.S1083* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | catalogued as COSV63964412; called by muse, mutect2
- MUC15 | c.979A>T p.I327L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); catalogued as COSV55553902; called by muse, mutect2, varscan2
- MUC16 | c.29131G>A p.E9711K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.069); catalogued as rs900840731, COSV67459233; called by muse, mutect2, varscan2
- MUC16 | c.22454C>A p.S7485Y | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV101200974, COSV67459236; called by muse, mutect2, varscan2
- MYH13 | c.239T>A p.M80K | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV52825455; called by muse, mutect2, varscan2
- MYH7 | c.3529del p.D1177Tfs*37 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as COSV100805608; called by mutect2, varscan2
- NAV3 | c.2527G>C p.D843H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57073797, COSV57106100; called by muse, varscan2
- NBEAL1 | c.4046C>G p.S1349C | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV71374112, COSV71374605; called by muse, mutect2, varscan2
- NEGR1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV60840575; called by muse, mutect2, varscan2
- NELL1 | c.2366C>A p.T789K | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV54255120; called by muse, mutect2, varscan2
- NES | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs756991221, COSV63960754; called by muse, mutect2
- NETO1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.173); catalogued as COSV55004824; called by muse, mutect2, varscan2
- NIF3L1 | c.643C>T p.Q215* (on ENST00000409020 / NM_001369444.1; = p.Q188* on NM_021824.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 55/182 reads (30%) | catalogued as COSV62900126; called by muse, mutect2, varscan2
- NINL | c.2785A>T p.S929C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as COSV54001014; called by muse, mutect2, varscan2
- NINL | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54001025; called by muse, varscan2
- NOS3 | c.916C>A p.P306T | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV52488609; called by muse, mutect2
- NUP43 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV61189341; called by muse, mutect2, varscan2
- OR10X1 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 72/138 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63767222; called by muse, mutect2, varscan2
- OR11G2 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV62132100; called by muse, mutect2, varscan2
- OR11H1 | c.264C>A p.N88K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV99421689; called by mutect2, varscan2
- OR12D3 | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV65827299; called by muse, mutect2, varscan2
- OR14A16 | c.23C>A p.T8N | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV62926463; called by muse, mutect2
- OR52N5 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57698645; called by muse, mutect2, varscan2
- OR5J2 | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as COSV100399150, COSV56620719; called by muse, mutect2, varscan2
- OR7C2 | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.009); catalogued as COSV50180437; called by muse, mutect2, varscan2
- OR7D4 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.433); catalogued as COSV58071502; called by muse, mutect2, varscan2
- ORAI1 | c.143C>G p.S48C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV57491261; called by muse, mutect2
- OTC | c.632T>A p.F211Y | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV50001254; called by muse, mutect2, varscan2
- OTOA | c.799C>T p.H267Y | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53752221; called by muse, mutect2, varscan2
- OTOF | c.227+1G>T p.X76_splice | Splice Site (SNP) | VAF 9/89 reads (10%) | catalogued as COSV55500808; called by muse, mutect2, varscan2
- OTOGL | c.1913G>C p.G638A (on ENST00000547103; = p.G629A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV101509056; called by muse, mutect2, varscan2
- OTUD7A | c.1910A>T p.Q637L (on ENST00000307050 / NM_001382637.1; = p.Q630L on NM_130901.3) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV61037709; called by muse, mutect2, varscan2
- P2RX5 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV56591490; called by muse, mutect2, varscan2
- PACRG | c.176C>A p.A59E | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV61302305; called by muse, mutect2, varscan2
- PACSIN2 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1199021489, COSV54318326; called by muse, mutect2, varscan2
- PALLD | c.544A>G p.I182V | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV54978300; called by muse, mutect2, varscan2
- PANK3 | c.628G>T p.G210W | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53322690; called by muse, mutect2, varscan2
- PATE1 | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778375180, COSV59824320; called by muse, mutect2, varscan2
- PAX9 | c.15C>A p.F5L | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV64061424, COSV64062620; called by muse, mutect2, varscan2
- PCDHA2 | c.1435G>T p.A479S | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV65366245; called by muse, mutect2, varscan2
- PCDHA5 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65351233; called by muse, mutect2, varscan2
- PCDHA8 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.158); catalogued as rs782524668, COSV65326007, COSV65329018; called by muse, mutect2, varscan2
- PCDHGB3 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV53929156; called by muse, mutect2, varscan2
- PDE4A | c.1189A>G p.M397V (on ENST00000380702 / NM_001111307.2; = p.M158V on NM_006202.3) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV53353803; called by muse, mutect2, varscan2
- PDLIM5 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV58746859; called by muse, mutect2, varscan2
- PEG3 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV55630530; called by muse, mutect2
- PHF1 | c.845C>G p.S282C | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV65702654; called by muse, mutect2
- PIGP | c.154+1G>A p.X52_splice | Splice Site (SNP) | VAF 21/127 reads (17%) | catalogued as rs755213101, COSV100308613; called by muse, mutect2, varscan2
- PIH1D1 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs751570759, COSV51806777; called by muse, mutect2, varscan2
- PIP5K1A | c.1543C>G p.Q515E (on ENST00000368888 / NM_001135638.2; = p.Q502E on NM_003557.3) | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as COSV62957967; called by muse, mutect2
- PIWIL1 | c.1628G>A p.R543K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV55345826; called by muse, mutect2, varscan2
- PKD1L1 | c.5355C>G p.I1785M | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV56962640; called by muse, mutect2, varscan2
- PKDREJ | c.3253C>T p.R1085C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as rs764096827, COSV53548525; called by muse, mutect2, varscan2
- PLA2R1 | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.095); catalogued as COSV99322509; called by muse, mutect2, varscan2
- PLCB2 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV53032340, COSV53032596, COSV99541523; called by muse, mutect2, varscan2
- PLIN1 | c.583G>C p.D195H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.582); catalogued as COSV55583389; called by muse, mutect2, varscan2
- PLIN5 | c.1268A>C p.H423P | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67850590; called by muse, mutect2, varscan2
- PMPCA | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV65509369; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.890G>C p.R297T | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.236); catalogued as COSV57964230; called by muse, mutect2, varscan2
- POLR1B | c.2500G>T p.G834W | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54494739, COSV54496900; called by muse, mutect2, varscan2
- POLR1G | c.1278G>C p.K426N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV50004033, COSV50005178; called by muse, mutect2, varscan2
- POTEF | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.901); catalogued as rs1009657282, COSV100664710; called by muse, mutect2, varscan2
- PPFIBP2 | c.2608G>C p.D870H | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV55076111; called by muse, mutect2, varscan2
- PPM1B | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56766215; called by muse, mutect2, varscan2
- PPOX | c.1343G>C p.G448A | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60526719, COSV60526985; called by muse, mutect2
- PPP4R1 | c.1480C>T p.P494S (on ENST00000400556 / NM_001042388.3; = p.P477S on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV53281361; called by muse, varscan2
- PRDM10 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58800616; called by muse, mutect2, varscan2
- PRKAA1 | c.993G>C p.L331F | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV57183720; called by muse, mutect2, varscan2
- PRKACB | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV65762734, COSV65762951; called by muse, mutect2, varscan2
- PRKAG3 | c.1399G>T p.V467L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.834); catalogued as COSV52101482; called by muse, mutect2, varscan2
- PRKRIP1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.588); catalogued as rs1554570310, COSV61349722; called by muse, mutect2, varscan2
- PRLR | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs139147779; called by muse, mutect2, varscan2
- PSG2 | c.531C>A p.S177R | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs1015026412, COSV61544984; called by muse, mutect2, varscan2
- PTPRD | c.4030G>A p.D1344N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV61938549; called by muse, mutect2, varscan2
- PTPRO | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1244706058, COSV55507494; called by muse, varscan2
- PTPRU | c.3227C>G p.P1076R | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60525742; called by muse, mutect2
- PTX3 | c.970G>C p.D324H | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1400107904, COSV55821508; called by muse, mutect2, varscan2
- RAD54L | c.1097A>T p.D366V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs759223529, COSV64335852; called by muse, mutect2, varscan2
- RAG2 | c.1012G>T p.V338F | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.15); catalogued as COSV57557228; called by muse, mutect2, varscan2
- RANBP2 | c.5776G>T p.D1926Y | Missense Mutation (SNP) | VAF 106/343 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV51699372, COSV51702907; called by muse, mutect2, varscan2
- RBAK | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1347401570, COSV62331204; called by muse, mutect2, varscan2
- RBFOX1 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV60954857, COSV60986955; called by muse, mutect2, varscan2
- RGR | c.686del p.G229Afs*15 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as COSV100812938, COSV100812952; called by mutect2, pindel, varscan2
- RGS20 | c.668T>A p.V223D (on ENST00000297313 / NM_170587.4; = p.V76D on NM_003702.4) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV99391927; called by muse, mutect2
- ROM1 | c.685C>A p.R229S | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV53882019, COSV53883339; called by muse, mutect2, varscan2
- ROS1 | c.6232A>T p.R2078W | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63853827; called by muse, mutect2, varscan2
- RPS4X | c.50A>G p.H17R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs1257811928, COSV60181636; called by muse, mutect2, varscan2
- RPS6KA3 | c.1416G>C p.Q472H | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV65387503; called by muse, mutect2, varscan2
- RSC1A1 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV60779485; called by muse, mutect2, varscan2
- RTL3 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.108); catalogued as rs1473456843, COSV58183832; called by muse, mutect2, varscan2
- RXRB | c.881G>C p.G294A | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV59495758, COSV59496898; called by muse, mutect2, varscan2
- RYR1 | c.8980G>C p.E2994Q | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV62094529; called by muse, mutect2, varscan2
- RYR2 | c.3016G>T p.V1006L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV100768902, COSV63678570; called by muse, mutect2, varscan2
- RYR2 | c.6812G>T p.G2271V | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV63670644, COSV63678579; called by muse, mutect2, varscan2
- RYR3 | c.6912C>A p.L2304= (on ENST00000389232; = p.L2305= on NM_001036.6) | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as COSV63109606; called by muse, mutect2, varscan2
- SBF2 | c.4787G>C p.W1596S | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56296685; called by muse, mutect2, varscan2
- SCG3 | c.218A>T p.D73V | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV55020817; called by muse, mutect2, varscan2
- SCYL1 | c.348G>C p.E116D | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.786); catalogued as COSV54211943; called by muse, mutect2
- SDK1 | c.6097G>T p.G2033W | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748836687, COSV67364254, COSV67371091; called by muse, mutect2, varscan2
- SELP | c.936G>A p.W312* | Nonsense Mutation (SNP) | VAF 16/134 reads (12%) | catalogued as COSV55250656; called by muse, mutect2, varscan2
- SEMA3A | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54867239; called by muse, mutect2
- SEPTIN2 | c.757G>T p.V253F | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV63632222; called by muse, mutect2
- SF3A1 | c.587A>G p.D196G | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53168321; called by muse, mutect2, varscan2
- SF3B3 | c.630C>G p.F210L | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV56786933; called by muse, mutect2
- SH3D19 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV58790059; called by muse, mutect2
- SIN3A | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64582492; called by muse, mutect2, varscan2
- SLAMF9 | c.834G>C p.L278F | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63636553; called by muse, mutect2, varscan2
- SLAMF9 | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 136/258 reads (53%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV63636296, COSV63636557, COSV63637341; called by muse, mutect2, varscan2
- SLC12A1 | c.2072C>A p.P691H | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66793807, COSV66795782; called by muse, mutect2, varscan2
- SLC22A4 | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as rs1245940397, COSV52357506; called by muse, mutect2, varscan2
- SLC2A11 | c.1408G>A p.E470K (on ENST00000345044 / NM_001024938.4; = p.E477K on NM_030807.5) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs776167108, COSV55390869; called by muse, mutect2, varscan2
- SLC30A10 | c.176A>G p.Y59C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.871); catalogued as COSV63071043; called by muse, mutect2
- SLC4A2 | c.894G>C p.Q298H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs533465790, COSV59656546; called by muse, mutect2, varscan2
- SLC9C2 | c.1062G>T p.L354F | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs768667261, COSV62945140; called by muse, mutect2, varscan2
- SLIT2 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs763158714, COSV56568329, COSV56572530; called by muse, mutect2, varscan2
- SLIT2 | c.1675C>T p.Q559* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV56568339, COSV99886216; called by muse, mutect2, varscan2
- SLIT3 | c.894G>C p.L298F | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV60603113; called by muse, mutect2, varscan2
- SMARCA5 | c.2494G>C p.E832Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV51643671; called by muse, mutect2, varscan2
- SMC3 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62419722; called by muse, mutect2, varscan2
- SMOC2 | c.289A>T p.T97S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.625); catalogued as COSV62436517; called by muse, mutect2, varscan2
- SMPD4 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV60079695; called by muse, mutect2, varscan2
- SON | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV51655432; called by muse, mutect2, varscan2
- SPAG4 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV65330317; called by muse, mutect2, varscan2
- SPATC1 | c.974C>G p.S325C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV66298591; called by muse, mutect2, varscan2
- SPIN2A | c.593C>A p.T198K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100888047; called by mutect2, varscan2
- SPPL2B | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs548345424, COSV66316918; called by muse, mutect2
- SRGAP2 | c.2441G>A p.R814K (on ENST00000624873 / NM_001170637.4; = p.R815K on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV55335912, COSV55336143; called by muse, mutect2, varscan2
- SRMS | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53920381; called by muse, mutect2
- ST8SIA2 | c.1034C>A p.P345Q | Missense Mutation (SNP) | VAF 32/94 reads (34%) | PolyPhen probably damaging (0.992); catalogued as COSV51568552, COSV51569948; called by muse, mutect2, varscan2
- STAG2 | c.1294C>G p.L432V | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as COSV54352046, COSV54355890; called by muse, mutect2, varscan2
- STT3A | c.1514T>A p.F505Y | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.107); catalogued as COSV67064557; called by muse, mutect2, varscan2
- SULF1 | c.2374G>C p.E792Q | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52678942; called by muse, mutect2, varscan2
- SULT1E1 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV56946754; called by muse, mutect2
- SUPT3H | c.856G>C p.E286Q (on ENST00000371460 / NM_181356.3; = p.E275Q on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs746933715, COSV100178595, COSV60937054; called by muse, mutect2
- SYCE1 | c.751G>A p.E251K (on ENST00000343131 / NM_001143764.3; = p.E215K on NM_130784.3) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.124); catalogued as COSV100385959, COSV58216696; called by muse, mutect2
- SYNCRIP | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.23); catalogued as COSV62287375; called by muse, mutect2, varscan2
- SYNE1 | c.12053C>T p.S4018L (on ENST00000367255 / NM_182961.4; = p.S3947L on NM_033071.3) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54956254; called by muse, mutect2, varscan2
- SYNE1 | c.3864G>C p.K1288N (on ENST00000367255 / NM_182961.4; = p.K1295N on NM_033071.3) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as COSV54956290, COSV54959654; called by muse, mutect2, varscan2
- SYT14 | c.586A>T p.N196Y | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.308); catalogued as COSV55052272; called by muse, mutect2, varscan2
- SZT2 | c.7303C>G p.P2435A (on ENST00000634258 / NM_001365999.1; = p.P2378A on NM_015284.4) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV65169030; called by muse, mutect2, varscan2
- TDRD1 | c.1570C>T p.Q524* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as COSV52589684; called by muse, mutect2, varscan2
- TG | c.6779C>T p.P2260L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV55072474; called by muse, mutect2, varscan2
- TGFBR2 | c.771G>C p.E257D | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.261); catalogued as COSV55447862; called by muse, mutect2, varscan2
- TIGD3 | c.1187T>A p.V396E | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52888872; called by muse, mutect2
- TIGD3 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.977); catalogued as COSV52888876; called by muse, mutect2
- TMEM132D | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.382); catalogued as rs749019418, COSV70601176; called by muse, mutect2, varscan2
- TMEM86A | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55010449; called by muse, mutect2, varscan2
- TNNI1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.025); catalogued as rs199605300; called by muse, mutect2, varscan2
- TNS2 | c.3979G>A p.D1327N (on ENST00000314250 / NM_170754.4; = p.D1337N on NM_015319.2) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs746187560, COSV56853318; called by muse, mutect2, varscan2
- TOGARAM1 | c.292C>G p.R98G | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV61887886, COSV61889333; called by muse, mutect2
- TOP2A | c.3134C>T p.S1045F | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.61); catalogued as COSV70732401, COSV70732921; called by muse, mutect2
- TP53BP1 | c.5313C>G p.F1771L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV53018567; called by muse, mutect2, varscan2
- TPTE | c.1631G>T p.S544I (on ENST00000618007 / NM_199261.4; = p.S526I on NM_199259.4) | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.039); catalogued as rs1409385803; called by muse, mutect2
- TRIM3 | c.1767C>G p.I589M | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61983602; called by muse, mutect2
- TRIM44 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.038); catalogued as COSV54983377; called by muse, mutect2, varscan2
- TRIM9 | c.1307-2A>G p.X436_splice | Splice Site (SNP) | VAF 9/77 reads (12%) | catalogued as COSV53615713; called by muse, mutect2, varscan2
- TRPS1 | c.277A>C p.K93Q (on ENST00000220888 / NM_001330599.2; = p.K106Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as COSV55235329; called by muse, mutect2, varscan2
- TSEN2 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.475); catalogued as COSV53188420, COSV53188469, COSV53189713; called by muse, mutect2, varscan2
- TTN | c.81170G>T p.W27057L (on ENST00000591111; = p.W19633L on NM_003319.4) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | PolyPhen possibly damaging (0.714); catalogued as COSV100628841, COSV59989443; called by muse, mutect2, varscan2
- TTN | c.55345G>T p.V18449L (on ENST00000591111; = p.V11025L on NM_003319.4) | Missense Mutation (SNP) | VAF 89/283 reads (31%) | PolyPhen probably damaging (0.99); catalogued as COSV59989519; called by muse, mutect2, varscan2
- TULP4 | c.1642G>C p.E548Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV65574371; called by muse, mutect2, varscan2
- TYR | c.239G>T p.W80L | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54473495; called by muse, mutect2, varscan2
- UGT2B28 | c.1156C>A p.H386N | Missense Mutation (SNP) | VAF 43/559 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV59431447, COSV59434365; called by muse, mutect2
- USB1 | c.546C>G p.F182L | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54682814; called by muse, mutect2
- USP34 | c.4355G>C p.R1452T | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as COSV68400228; called by muse, mutect2, varscan2
- WBP2NL | c.428G>C p.R143T | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.239); catalogued as COSV60919150; called by muse, mutect2, varscan2
- WDSUB1 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100701787; called by muse, mutect2, varscan2
- YBX3 | c.476G>A p.G159D | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54385140; called by muse, mutect2, varscan2
- YY2 | c.989C>G p.T330R | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63411155, COSV63412530; called by muse, mutect2, varscan2
- ZC3H18 | c.1532G>C p.R511T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99963938; called by muse, mutect2, varscan2
- ZFP30 | c.21G>A p.M7I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs748113943, COSV63622523; called by muse, mutect2, varscan2
- ZFYVE26 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61327014, COSV61329162; called by muse, mutect2, varscan2
- ZNF112 | c.754C>T p.Q252* (on ENST00000337401 / NM_001083335.2; = p.Q246* on NM_013380.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | catalogued as COSV61619600; called by muse, mutect2, varscan2
- ZNF223 | c.544G>T p.G182* | Nonsense Mutation (SNP) | VAF 49/180 reads (27%) | catalogued as COSV71571873; called by muse, mutect2, varscan2
- ZNF223 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV101462610; called by muse, mutect2, varscan2
- ZNF479 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 51/144 reads (35%) | catalogued as COSV58637660, COSV58641431; called by muse, mutect2, varscan2
- ZNF483 | c.1542G>C p.Q514H | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58515265; called by muse, mutect2, varscan2
- ZNF547 | c.563A>G p.K188R | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs767341747, COSV56580197; called by muse, mutect2, varscan2
- ZNF562 | c.1165C>G p.Q389E (on ENST00000453372 / NM_001130032.2; = p.Q317E on NM_017656.4) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53333372; called by muse, mutect2, varscan2
- ZNF610 | c.855G>T p.E285D | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV58344380; called by muse, mutect2, varscan2
- ZNF709 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV67194524; called by muse, mutect2, varscan2
- ZNF786 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.138); catalogued as COSV60275195; called by muse, mutect2, varscan2
- ZNF846 | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV67411978; called by muse, mutect2, varscan2
- ZNF92 | c.1198G>T p.E400* (on ENST00000328747 / NM_152626.4; = p.E331* on NM_007139.4) | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV60873837; called by muse, mutect2, varscan2
- ZSCAN1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as rs757274442, COSV56601596, COSV56601881; called by muse, mutect2, varscan2
- ADGRG4 | c.6598del p.V2200* | Frame Shift Del (DEL) | VAF 53/125 reads (42%) | called by mutect2, pindel, varscan2
- ATM | c.3085del p.T1029Qfs*10 | Frame Shift Del (DEL) | VAF 49/95 reads (52%) | called by mutect2, pindel, varscan2
- EYA3 | c.942del p.I315Sfs*21 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel, varscan2
- FRG2C | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2
- IGHV1OR21-1 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 26/506 reads (5%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.691); called by muse, mutect2
- IGHV3-73 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- KIR2DS4 | c.352C>A p.L118M | Missense Mutation (SNP) | VAF 85/408 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MRPL43 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.297); called by muse, mutect2
- POTEF | c.2861G>C p.R954P | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.685); called by mutect2, varscan2
- SERPINA1 | c.522del p.E175Kfs*35 | Frame Shift Del (DEL) | VAF 79/150 reads (53%) | called by mutect2, pindel, varscan2
- TPRG1L | c.611dup p.S205Ifs*52 | Frame Shift Ins (INS) | VAF 34/130 reads (26%) | called by mutect2, pindel, varscan2
- TRAV14DV4 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TRAV9-1 | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); called by muse, mutect2
- ULK2 | c.1424_1438del p.Y475_P479del | In Frame Del (DEL) | VAF 67/154 reads (44%) | called by mutect2, pindel, varscan2
- ABHD16A | c.6G>A p.A2= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV65442750; called by muse, mutect2, varscan2
- ACSF3 | c.981G>A p.L327= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs1477633208, COSV58077838; called by muse, mutect2, varscan2
- ADGRL3 | c.2916G>T p.G972= (on ENST00000506720 / NM_001322402.2; = p.G904= on NM_015236.6) | Silent (SNP) | VAF 73/166 reads (44%) | catalogued as COSV101546911, COSV72230217; called by muse, mutect2, varscan2
- AMER1 | c.1269G>T p.L423= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV57659057; called by muse, mutect2, varscan2
- ARHGAP11A | c.705A>T p.A235= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV64380822; called by muse, mutect2
- ATP2B4 | c.2262G>A p.A754= | Silent (SNP) | VAF 21/203 reads (10%) | catalogued as rs750641764, COSV58176535; called by muse, mutect2, varscan2
- BBOX1 | c.759C>T p.S253= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99589531; called by muse, mutect2, varscan2
- BMP2K | c.2112C>G p.G704= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as COSV55009221; called by muse, mutect2, varscan2
- BRCA1 | c.156C>A p.L52= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV58788179; called by muse, mutect2
- CCDC6 | c.162C>T p.F54= | Silent (SNP) | VAF 54/124 reads (44%) | catalogued as COSV54055958; called by muse, mutect2, varscan2
- CNKSR1 | c.1491C>G p.L497= (on ENST00000374253 / NM_001297647.2; = p.L490= on NM_006314.3) | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV58792824; called by muse, mutect2, varscan2
- CNN1 | c.189C>T p.F63= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV52955751; called by muse, mutect2, varscan2
- COL25A1 | c.198C>G p.L66= | Silent (SNP) | VAF 10/192 reads (5%) | catalogued as COSV67649009; called by muse, mutect2
- CPQ | c.975G>A p.K325= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV55142992; called by muse, mutect2
- CSPP1 | c.702A>T p.T234= (on ENST00000676605; = p.T193= on NM_024790.6) | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV51582958; called by muse, mutect2, varscan2
- CST1 | c.318C>T p.F106= | Silent (SNP) | VAF 57/129 reads (44%) | catalogued as COSV59055032; called by muse, mutect2, varscan2
- CUL7 | c.609G>C p.L203= | Silent (SNP) | VAF 14/214 reads (7%) | catalogued as COSV54815298; called by muse, mutect2
- DNAH1 | c.5394C>G p.L1798= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV70228148; called by muse, mutect2, varscan2
- DSP | c.6084A>G p.K2028= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV65792273, COSV65794270; called by muse, mutect2, varscan2
- DYNC2H1 | c.36C>T p.F12= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV62088698, COSV62091662; called by muse, mutect2, varscan2
- EFCAB7 | c.1125G>A p.R375= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV64314357; called by muse, mutect2, varscan2
- EGR2 | c.1398C>T p.L466= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as rs1483612429, COSV54346636; called by muse, mutect2, varscan2
- EPX | c.1575C>T p.T525= | Silent (SNP) | VAF 52/116 reads (45%) | catalogued as rs1246633703, COSV56595859; called by muse, mutect2, varscan2
- FAM83C | c.1434C>A p.P478= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV65582721; called by muse, mutect2, varscan2
- FCHSD2 | c.1674C>G p.L558= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100238561, COSV60808466; called by muse, mutect2
- FOXA1 | c.1362C>T p.A454= | Silent (SNP) | VAF 16/159 reads (10%) | catalogued as COSV51645144; called by muse, mutect2, varscan2
- GABRR1 | c.366C>T p.L122= | Silent (SNP) | VAF 48/226 reads (21%) | catalogued as COSV65619181; called by muse, mutect2, varscan2
- GBA | c.75C>G p.L25= | Silent (SNP) | VAF 31/454 reads (7%) | catalogued as COSV59169489; called by muse, mutect2
- GLI1 | c.1503C>G p.L501= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV57360653, COSV57366719; called by muse, mutect2, varscan2
- GLRB | c.1245G>A p.L415= | Silent (SNP) | VAF 52/96 reads (54%) | catalogued as COSV52415719; called by muse, mutect2, varscan2
- GOLGA3 | c.2607G>A p.L869= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV52629122; called by muse, mutect2, varscan2
- GPR52 | c.831G>C p.L277= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as COSV52288853, COSV52315433; called by muse, mutect2, varscan2
- GRM1 | c.3006C>A p.L1002= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as COSV51128647; called by muse, mutect2, varscan2
- GRSF1 | c.1419G>A p.L473= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV54655025; called by muse, mutect2
- GTF2H4 | c.1077C>T p.I359= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as COSV52558496; called by muse, mutect2, varscan2
- HAL | c.210C>G p.L70= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV54117325; called by muse, mutect2, varscan2
- HECW2 | c.3744C>T p.V1248= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as COSV53656003; called by muse, mutect2, varscan2
- HSPG2 | c.2436G>T p.R812= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as rs753683050, COSV65970708; called by muse, mutect2, varscan2
- IER2 | c.100C>T p.L34= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1042136822, COSV52847792; called by muse, mutect2, varscan2
- KCNH1 | c.717C>T p.V239= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV55077121; called by muse, mutect2, varscan2
- KCNJ3 | c.1500C>T p.F500= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV54534769, COSV99716666; called by muse, varscan2
- KDM5A | c.2763C>T p.V921= | Silent (SNP) | VAF 24/154 reads (16%) | catalogued as COSV66991793; called by muse, mutect2, varscan2
- KIAA2026 | c.615G>A p.T205= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs764757394, COSV67354383; called by mutect2, varscan2
- KIF21B | c.2241G>A p.K747= | Silent (SNP) | VAF 21/342 reads (6%) | catalogued as COSV59755825; called by muse, mutect2
- KRT80 | c.636C>T p.F212= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as rs1254362503, COSV57548536; called by muse, mutect2, varscan2
- LGR4 | c.1545T>C p.H515= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV64863995; called by muse, mutect2, varscan2
- LRRC8E | c.1269C>G p.L423= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV60717683; called by muse, mutect2, varscan2
- LYRM2 | c.27G>T p.A9= | Silent (SNP) | VAF 34/194 reads (18%) | catalogued as COSV101021314, COSV65520357; called by muse, mutect2, varscan2
- MAPK13 | c.195C>T p.F65= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV52982784; called by muse, mutect2, varscan2
- MFAP3L | c.813G>A p.V271= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV64372044; called by muse, mutect2, varscan2
- MFSD5 | c.1042C>T p.L348= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV61565200, COSV61565391; called by muse, mutect2, varscan2
- MPP3 | c.1170G>C p.L390= | Silent (SNP) | VAF 42/247 reads (17%) | catalogued as COSV68197951, COSV68199413; called by muse, mutect2, varscan2
- MSH3 | c.3312C>G p.L1104= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV54145031, COSV54149916; called by mutect2, varscan2
- MUC6 | c.2820G>A p.A940= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs371296189; called by muse, mutect2, varscan2
- NAV3 | c.4875T>A p.S1625= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV57073816; called by muse, mutect2, varscan2
- NCKAP1 | c.3264A>G p.L1088= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs1178404642, COSV62940616; called by muse, mutect2
- NEB | c.7752G>A p.Q2584= | Silent (SNP) | VAF 148/470 reads (31%) | catalogued as COSV50807654, COSV51420991; called by muse, mutect2, varscan2
- NFE2L1 | c.366C>T p.L122= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as rs1007244219, COSV62583061, COSV62583409; called by muse, mutect2
- NOL4 | c.1006C>T p.L336= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV52344443; called by muse, mutect2, varscan2
- NR3C1 | c.606G>A p.G202= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV51541996; called by muse, mutect2, varscan2
- NUP205 | c.4053C>G p.L1351= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV53657612, COSV99606958; called by muse, mutect2, varscan2
- OMA1 | c.135T>C p.H45= | Silent (SNP) | VAF 48/129 reads (37%) | catalogued as rs1056534303, COSV62255031; called by muse, mutect2, varscan2
- OR10AG1 | c.87C>A p.I29= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as COSV56632468, COSV56632502; called by muse, mutect2, varscan2
- OR10Z1 | c.339C>T p.F113= | Silent (SNP) | VAF 30/261 reads (11%) | catalogued as rs1176055881, COSV63524160; called by muse, mutect2, varscan2
- OR2A12 | c.633C>T p.C211= | Silent (SNP) | VAF 66/200 reads (33%) | catalogued as COSV68821261; called by muse, mutect2, varscan2
- OR2G3 | c.36C>T p.F12= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV60681288; called by muse, mutect2, varscan2
- OR2T12 | c.588C>T p.A196= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as COSV58777131; called by muse, mutect2, varscan2
- PARP6 | c.435G>C p.L145= | Silent (SNP) | VAF 54/302 reads (18%) | catalogued as COSV53002741; called by muse, mutect2, varscan2
- PCDH9 | c.291C>G p.L97= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs760111209, COSV60542390; called by muse, mutect2, varscan2
- PCDHGA4 | c.2187C>T p.A729= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs1227374616, COSV53929137, COSV99540628; called by muse, mutect2, varscan2
- PCDHGA7 | c.1668T>C p.N556= | Silent (SNP) | VAF 38/164 reads (23%) | catalogued as COSV53929172; called by muse, mutect2, varscan2
- PHF2 | c.3240G>A p.Q1080= | Silent (SNP) | VAF 37/175 reads (21%) | catalogued as COSV63680161, COSV63681924; called by muse, mutect2, varscan2
- PIGA | c.1347T>C p.S449= | Silent (SNP) | VAF 32/147 reads (22%) | catalogued as COSV61237393; called by muse, mutect2, varscan2
- PLA2G4F | c.2472G>A p.L824= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs750488438, COSV51826340; called by muse, mutect2, varscan2
- PLCH2 | c.3642C>A p.P1214= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV53941523; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1294T>C p.L432= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV65047669; called by muse, mutect2, varscan2
- POC1A | c.774G>C p.L258= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV56591025; called by muse, mutect2, varscan2
- POLDIP3 | c.843G>A p.K281= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as rs1394351168, COSV52808808; called by muse, mutect2, varscan2
- POM121L12 | c.369G>T p.G123= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV101374984, COSV68692653; called by muse, mutect2, varscan2
- PRUNE1 | c.1092C>T p.D364= | Silent (SNP) | VAF 11/184 reads (6%) | catalogued as COSV54846572; called by muse, mutect2
- PTGER4 | c.1185C>T p.L395= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV56720631; called by muse, mutect2, varscan2
- RAB11FIP3 | c.978G>A p.E326= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV51932639; called by muse, mutect2, varscan2
- RDH14 | c.990G>A p.V330= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as COSV67118723, COSV67118892; called by muse, mutect2, varscan2
- RELN | c.879C>T p.D293= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV58996295; called by muse, mutect2, varscan2
- RERGL | c.498C>T p.I166= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV57461515, COSV99967809; called by muse, mutect2, varscan2
- RFPL1 | c.432C>A p.L144= | Silent (SNP) | VAF 26/135 reads (19%) | catalogued as COSV62977697; called by muse, mutect2, varscan2
- RHOT1 | c.1083A>G p.G361= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as COSV61715070; called by muse, mutect2, varscan2
- RIMKLA | c.1002A>G p.G334= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV68909734; called by muse, mutect2, varscan2
- RP1L1 | c.5802G>A p.E1934= | Silent (SNP) | VAF 46/178 reads (26%) | catalogued as rs752992057, COSV66754071; called by muse, varscan2
- RPA4 | c.579C>T p.N193= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs778586646, COSV61265832; called by muse, mutect2, varscan2
- RYR2 | c.2196C>G p.L732= | Silent (SNP) | VAF 28/205 reads (14%) | catalogued as COSV63678562; called by muse, mutect2, varscan2
- SCNN1D | c.270G>T p.L90= (on ENST00000338555; = p.L254= on NM_001130413.4) | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV57641022; called by mutect2, varscan2
- SH3D21 | c.1125G>A p.K375= (on ENST00000453908 / NM_001162530.2; = p.K264= on NM_024676.5) | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV54633982; called by muse, mutect2, varscan2
- SI | c.37C>T p.L13= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV52273891; called by muse, mutect2
- SIGLEC11 | c.2037G>A p.L679= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs754674773, COSV68567672; called by muse, mutect2, varscan2
- SIM1 | c.1836C>A p.P612= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as rs779153540, COSV53490905; called by muse, mutect2, varscan2
- SIM1 | c.1242G>A p.T414= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs760403107, COSV53490919; called by muse, mutect2, varscan2
- SLC22A3 | c.447C>G p.V149= | Silent (SNP) | VAF 25/186 reads (13%) | catalogued as COSV51712607; called by muse, mutect2, varscan2
- SPPL2B | c.339C>G p.R113= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV66316756, COSV66316920, COSV66317183; called by muse, mutect2
- SRD5A3 | c.882C>G p.L294= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as COSV51711689, COSV51711752; called by muse, mutect2
- STAP2 | c.1002C>T p.V334= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs1240556830, COSV55695655; called by muse, varscan2
- STK25 | c.840C>G p.L280= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV50870472; called by muse, mutect2, varscan2
- STRIP2 | c.396C>G p.L132= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs771426797, COSV50803863, COSV50808323; called by muse, mutect2, varscan2
- SYN2 | c.12C>T p.F4= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV70285198; called by muse, mutect2, varscan2
- SYNPO | c.1831C>T p.L611= (on ENST00000394243 / NM_001166208.2; = p.L367= on NM_007286.6) | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV56939511; called by muse, mutect2, varscan2
- TAF1L | c.3105G>A p.E1035= | Silent (SNP) | VAF 42/265 reads (16%) | catalogued as COSV54260531; called by muse, mutect2, varscan2
- TASP1 | c.522A>C p.A174= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV61812519; called by muse, mutect2, varscan2
- TCEANC | c.798G>A p.L266= (on ENST00000380600 / NM_001297563.2; = p.L296= on NM_152634.4) | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV59039608; called by muse, mutect2
- TMEM132D | c.2685C>T p.P895= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV101242943, COSV67159815; called by muse, mutect2, varscan2
- TNFRSF13C | c.513T>C p.T171= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV52169463; called by muse, varscan2
- TNN | c.258C>T p.F86= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV53424610, COSV99512656; called by muse, mutect2, varscan2
- TPX2 | c.78A>T p.G26= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV55918735; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1122G>C p.L374= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV60675549; called by muse, mutect2, varscan2
- TRIM50 | c.288C>G p.L96= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV52719717; called by muse, mutect2, varscan2
- TRIO | c.1029G>A p.R343= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs1373850452, COSV60081844; called by muse, mutect2, varscan2
- TTN | c.51276C>G p.L17092= (on ENST00000591111; = p.L9668= on NM_003319.4) | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as rs766306616, COSV59989551; called by muse, mutect2, varscan2
- TXNDC2 | c.1605T>C p.D535= (on ENST00000306084 / NM_001098529.2; = p.D468= on NM_032243.6) | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV60152843; called by muse, mutect2, varscan2
- URB2 | c.3036C>G p.L1012= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV50984798, COSV99272126; called by muse, mutect2, varscan2
- USP11 | c.888G>A p.S296= (on ENST00000218348; = p.S253= on NM_001371072.1) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1216184460, COSV54473267; called by muse, mutect2, varscan2
- VAX2 | c.693G>A p.P231= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs781851281, COSV52265604; called by muse, mutect2, varscan2
- WASHC2C | c.3504G>A p.K1168= (on ENST00000336378; = p.K1147= on NM_015262.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- WNK1 | c.2805A>G p.P935= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs555482187, COSV60030477; called by muse, mutect2, varscan2
- ZHX3 | c.696C>T p.F232= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as rs890643959, COSV58382529; called by muse, mutect2, varscan2
- ZNF709 | c.1371C>T p.F457= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as rs774146994, COSV67194516; called by muse, varscan2
- AL132655.6 | chr20:58840436 G>A | 5'Flank (SNP) | VAF 13/100 reads (13%) | catalogued as COSV58332512; called by muse, mutect2, varscan2
- C22orf15 | c.325+10A>C | Intron (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- DDX41 | c.*919G>C | 3'UTR (SNP) | VAF 22/131 reads (17%) | catalogued as COSV57251785; called by muse, mutect2, varscan2
- DNM1P46 | n.561C>A | RNA (SNP) | VAF 8/20 reads (40%) | catalogued as rs753852423; called by muse, varscan2
- KIR3DX1 | n.976C>T | RNA (SNP) | VAF 27/124 reads (22%) | catalogued as COSV55597888; called by muse, mutect2, varscan2
- NRXN1 | c.3365-109895G>T | Intron (SNP) | VAF 5/13 reads (38%) | catalogued as rs1453397819, COSV58446101; called by muse, mutect2
- PIGK | c.987-6768G>C | Intron (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- SSX9P | n.26C>T | RNA (SNP) | VAF 54/259 reads (21%) | catalogued as rs782654039; called by muse, mutect2, varscan2
- Vault | n.45_46dup | RNA (INS) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
